Somatic mutation profile of tumor specimen HCM-CSHL-0077-C25-01B (aliquot HCM-CSHL-0077-C25-01B-11D-A78L-36) from HCMI case HCM-CSHL-0077-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.3 years (24,206 days).
Specimen HCM-CSHL-0077-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6b055f9-c832-4029-acbb-a081a169bce6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0077-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0077-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07229cb1-64ba-45bb-b2b7-15694f35f35c

The open-access MAF lists 73 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Nonsense Mutation 4, RNA 4, Intron 4, Frame Shift Ins 3, 5'Flank 2, 5'UTR 2, Frame Shift Del 1, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 77/175 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 101/212 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.2116C>G p.P706A | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV60096936; called by muse, mutect2
- ATP10A | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs756615616, COSV63522017; called by muse, mutect2, varscan2
- CD79A | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs782714583, COSV55739002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPB | c.4590G>A p.S1530= | Splice Region (SNP) | VAF 75/195 reads (38%) | catalogued as rs200886335; called by muse, mutect2, varscan2
- CUTC | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs768955316; called by muse, mutect2, varscan2
- DOK5 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 23/223 reads (10%) | catalogued as rs745756056, COSV52815843, COSV52820481; called by muse, mutect2, varscan2
- ERBB4 | c.2779C>T p.R927* | Nonsense Mutation (SNP) | VAF 46/263 reads (17%) | catalogued as rs537458255, COSV61460348; called by muse, mutect2, varscan2
- FAM71C | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146401531; called by muse, mutect2, varscan2
- GLI3 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 100/530 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206529384, COSV67886118, COSV67889519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPACAM | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1427700277; called by muse, mutect2, varscan2
- HNRNPA1 | c.342A>C p.E114D | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV99043726; called by muse, mutect2, varscan2
- KCND3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56192249; called by muse, mutect2, varscan2
- KNCN | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs200362801; called by muse, mutect2, varscan2
- MAS1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs752123270, COSV53121262; called by muse, mutect2, varscan2
- MUC16 | c.20027C>G p.A6676G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.096); catalogued as COSV101201076, COSV67464315; called by muse, mutect2, varscan2
- PPTC7 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs755061887, COSV62826808; called by muse, mutect2, varscan2
- RIMS2 | c.2912G>T p.R971L (on ENST00000666250 / NM_001348490.2; = p.R779L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51668611, COSV99169380; called by muse, mutect2, varscan2
- SEMA4C | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1435645867, COSV59692313; called by muse, mutect2, varscan2
- SMAD4 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684480; called by muse, mutect2, varscan2
- SPATA31E1 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs774990542; called by muse, mutect2, varscan2
- TNR | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as rs527422558; called by muse, mutect2
- ZNF366 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV59216354; called by muse, mutect2, varscan2
- AMER1 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CEP350 | c.5203A>C p.K1735Q | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHD9 | c.6376dup p.R2126Kfs*6 | Frame Shift Ins (INS) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- CHST14 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT3 | c.387+1G>A p.X129_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- DKK3 | c.362_365del p.N121Rfs*135 | Frame Shift Del (DEL) | VAF 66/237 reads (28%) | called by mutect2, pindel, varscan2
- DNAH3 | c.9126C>A p.S3042R | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNAH5 | c.10145dup p.L3382Ffs*6 | Frame Shift Ins (INS) | VAF 108/324 reads (33%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.2110A>T p.T704S | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GLI3 | c.45dup p.V16Sfs*2 | Frame Shift Ins (INS) | VAF 50/333 reads (15%) | called by mutect2, pindel, varscan2
- HGF | c.515T>A p.L172Q | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV1-9 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 101/631 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MORN1 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 66/237 reads (28%) | called by muse, mutect2, varscan2
- MPPED2 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5L2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OSGIN2 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 13/341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OVCH1 | c.3055A>G p.I1019V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PCDH10 | c.1611G>T p.K537N | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB12 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASL10A | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPS6KA6 | c.1885A>T p.T629S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.09); called by muse, mutect2
- RYR3 | c.4429A>T p.S1477C | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2
- SOAT1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CERKL | c.990C>T p.V330= (on ENST00000339098 / NM_001030311.2; = p.V304= on NM_201548.5) | Silent (SNP) | VAF 35/288 reads (12%) | catalogued as rs139270710; called by muse, mutect2, varscan2
- CLEC17A | c.1083T>C p.D361= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- GOLGB1 | c.5193C>T p.V1731= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1173C>G p.L391= | Silent (SNP) | VAF 51/70 reads (73%) | called by muse, mutect2, varscan2
- HSPB3 | c.231G>T p.V77= | Silent (SNP) | VAF 87/520 reads (17%) | called by muse, mutect2, varscan2
- KTI12 | c.504C>A p.A168= | Silent (SNP) | VAF 42/166 reads (25%) | called by muse, mutect2, varscan2
- LMOD2 | c.73C>T p.L25= | Silent (SNP) | VAF 109/314 reads (35%) | catalogued as COSV101505416; called by muse, mutect2, varscan2
- NR0B1 | c.486G>A p.A162= | Silent (SNP) | VAF 68/266 reads (26%) | called by muse, mutect2, varscan2
- PUF60 | c.498C>T p.T166= (on ENST00000526683 / NM_001362896.2; = p.T149= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs1208365639; called by muse, mutect2, varscan2
- RALBP1 | c.1317C>G p.L439= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV50036294; called by muse, mutect2, varscan2
- RIDA | c.57A>G p.G19= | Silent (SNP) | VAF 73/201 reads (36%) | called by muse, mutect2, varscan2
- SCGB2B2 | c.267C>T p.N89= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs546541304; called by muse, mutect2, varscan2
- SIGLEC16 | c.303G>A p.P101= | Silent (SNP) | VAF 111/284 reads (39%) | catalogued as rs748421105; called by muse, mutect2, varscan2
- ANKRD42 | chr11:83193933 G>A | 5'Flank (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892782 G>A | 5'Flank (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65795C>T | Intron (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- FIBP | c.411+61_411+63del | Intron (DEL) | VAF 86/291 reads (30%) | called by mutect2, pindel, varscan2
- HDAC8 | c.-61C>T | 5'UTR (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- INSR | c.2231+38A>G | Intron (SNP) | VAF 128/329 reads (39%) | catalogued as rs1325123938; called by muse, mutect2, varscan2
- MYADML | n.601C>T | RNA (SNP) | VAF 30/195 reads (15%) | catalogued as rs781180336; called by muse, mutect2, varscan2
- NPIPP1 | n.500G>A | RNA (SNP) | VAF 122/408 reads (30%) | called by muse, mutect2, varscan2
- OCA2 | c.-13C>T | 5'UTR (SNP) | VAF 53/388 reads (14%) | catalogued as COSV100667511; called by muse, mutect2, varscan2
- RTL8B | c.*386A>T | 3'UTR (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- TLK1 | c.330+1121T>C | Intron (SNP) | VAF 42/132 reads (32%) | catalogued as rs965331812; called by muse, mutect2, varscan2
- TUBB7P | n.1230C>T | RNA (SNP) | VAF 54/286 reads (19%) | catalogued as rs782470537; called by muse, mutect2, varscan2
- ZNF849P | n.1080A>T | RNA (SNP) | VAF 27/244 reads (11%) | called by muse, varscan2
